Gene-level copy-number profile of tumor specimen TCGA-AA-A00K-01A from TCGA case TCGA-AA-A00K, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.9 years (29,189 days).
Specimen TCGA-AA-A00K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.02053079-62b7-4df6-9c3f-b37af76082ea.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A00K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 389 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b0d0ae7-4bfd-4cd4-82fa-391057254e6b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 483; copy number 2: 50,792; copy number 3: 8,743; copy number 4: 105; copy number 5: 105; copy number 7: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-A00K-01): tumor purity 0.67, ploidy 2.12, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 111 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,344,736–22,282,872, 105 genes, copy number 5 (broad region; genes not listed).
- chr17:46,029,916–46,225,389, 1 gene, copy number 7 (within-gene range 2–7): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 7: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 483. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
